Somatic mutation profile of tumor specimen TCGA-CW-5583-01A (aliquot TCGA-CW-5583-01A-02D-1534-10) from TCGA case TCGA-CW-5583, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.1 years (18,666 days).
Specimen TCGA-CW-5583-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db681625-ae47-4ca3-b5e2-582cfd0a04af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CW-5583-11A (Solid Tissue Normal), aliquot TCGA-CW-5583-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5ea82e3-5c5f-494d-9b16-8f0b61260542

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Frame Shift Del 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR2 | c.2534A>T p.E845V | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV65809218; called by muse, mutect2
- BMPR2 | c.2536A>T p.M846L | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV65809224; called by muse, mutect2
- CTSS | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 150/443 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64566299; called by muse, mutect2, varscan2
- EPHA10 | c.2180G>A p.S727N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV57623869; called by muse, mutect2
- ISL1 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57933436; called by muse, mutect2, varscan2
- LRP11 | c.768G>T p.M256I | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV53333833, COSV53335415; called by muse, mutect2, varscan2
- LRRK1 | c.5663C>T p.S1888F | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV52610661; called by muse, mutect2
- MORC2 | c.2824C>G p.L942V (on ENST00000397641 / NM_001303256.3; = p.L880V on NM_014941.3) | Missense Mutation (SNP) | VAF 96/291 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53198429; called by muse, mutect2, varscan2
- MRPL14 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.051); catalogued as COSV64394547; called by muse, mutect2, varscan2
- NOTCH3 | c.3433C>G p.L1145V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as COSV54634392; called by muse, mutect2, varscan2
- PTGS2 | c.1625T>G p.F542C | Missense Mutation (SNP) | VAF 112/359 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66569227; called by muse, mutect2, varscan2
- PTPRN | c.2635G>A p.G879S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs548633041, COSV55347735, COSV55350153; called by muse, mutect2, varscan2
- SHTN1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 113/417 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53382128; called by muse, mutect2, varscan2
- TFDP3 | c.1045A>C p.N349H | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV59536708; called by muse, mutect2, varscan2
- TRAP1 | c.775T>C p.S259P | Missense Mutation (SNP) | VAF 96/300 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1339878786, COSV55916175; called by muse, mutect2, varscan2
- UBE3C | c.667A>G p.I223V | Missense Mutation (SNP) | VAF 169/537 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1322483088, COSV61953023; called by muse, mutect2, varscan2
- USP15 | c.2654G>C p.G885A (on ENST00000280377 / NM_001351159.2; = p.G856A on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/779 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54791751, COSV54799722, COSV99738441; called by muse, mutect2, varscan2
- VHL | c.562del p.L188Wfs*14 | Frame Shift Del (DEL) | VAF 45/118 reads (38%) | catalogued as CD071417, CM951300, COSV56561468, COSV56563214; called by mutect2, pindel, varscan2
- ZNF653 | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs562892839, COSV53402868; called by muse, mutect2, varscan2
- AHNAK2 | c.3057del p.L1020Wfs*13 | Frame Shift Del (DEL) | VAF 38/136 reads (28%) | called by mutect2, pindel, varscan2
- MYH3 | c.4509_4510del p.N1503Kfs*16 | Frame Shift Del (DEL) | VAF 101/381 reads (27%) | called by mutect2, pindel*, varscan2*
- OSBPL1A | c.678_681del p.G227Ifs*8 | Frame Shift Del (DEL) | VAF 22/126 reads (17%) | called by mutect2, pindel, varscan2
- EGFL8 | c.264G>A p.E88= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV61247587; called by muse, mutect2, varscan2
- IFI16 | c.897G>A p.K299= | Silent (SNP) | VAF 113/338 reads (33%) | catalogued as COSV55533724; called by muse, mutect2, varscan2
- PON3 | c.570G>T p.L190= | Silent (SNP) | VAF 39/425 reads (9%) | catalogued as COSV55699225; called by muse, mutect2
- PPP3CA | c.960A>C p.A320= | Silent (SNP) | VAF 32/416 reads (8%) | catalogued as COSV100548005; called by muse, mutect2
- RGMB | c.153A>T p.P51= (on ENST00000513185 / NM_001366508.1; = p.P92= on NM_001012761.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV57565530; called by muse, mutect2, varscan2
- TANGO6 | c.2061C>A p.T687= | Silent (SNP) | VAF 119/413 reads (29%) | catalogued as COSV55764991; called by muse, mutect2, varscan2
- TP53BP2 | c.2388A>T p.P796= (on ENST00000343537 / NM_001031685.3; = p.P667= on NM_005426.2) | Silent (SNP) | VAF 131/373 reads (35%) | catalogued as COSV59068331; called by muse, mutect2, varscan2
